Somatic mutation profile of tumor specimen TCGA-A6-2674-01A (aliquot TCGA-A6-2674-01A-02D-1953-10) from TCGA case TCGA-A6-2674, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 72.0 years (26,292 days).
Specimen TCGA-A6-2674-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78f65557-969c-4311-9519-0f6dd30813fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-2674-10A (Blood Derived Normal), aliquot TCGA-A6-2674-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25ac9fa8-f80c-44c7-bb54-94ee3b447f08

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PYGM | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780246932, CM092502, COSV99377718; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BEST3 | c.1162C>T p.R388W | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs770709086, COSV58302523; called by muse, mutect2, varscan2
- CRACD | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 57/430 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.509); catalogued as COSV99950127; called by muse, mutect2, varscan2
- CUX2 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1364584717, COSV55636062; called by muse, mutect2, varscan2
- DOT1L | c.133T>G p.C45G | Missense Mutation (SNP) | VAF 142/709 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101288882; called by muse, varscan2
- FOLH1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); catalogued as COSV57049487; called by mutect2, varscan2
- LAMA5 | c.4718G>A p.R1573H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs774677106, COSV53356578; called by mutect2, varscan2
- OSBP | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99803483; called by muse, mutect2, varscan2
- SOBP | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.571); catalogued as COSV58004112; called by muse, mutect2, varscan2
- SOX1 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58378395; called by muse, mutect2, varscan2
- SYNE3 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs769547536, COSV100516641, COSV99043712; called by muse, mutect2, varscan2
- AHDC1 | c.531C>T p.I177= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV55942063; called by muse, mutect2, varscan2
- ESPNL | c.1047G>A p.T349= | Silent (SNP) | VAF 25/160 reads (16%) | catalogued as rs371983774; called by muse, mutect2, varscan2
- FLOT2 | c.975G>A p.A325= | Silent (SNP) | VAF 32/171 reads (19%) | catalogued as rs770754509, COSV67529287; called by muse, mutect2, varscan2
- GDF7 | c.1263C>T p.S421= | Silent (SNP) | VAF 20/118 reads (17%) | catalogued as rs747585645, COSV99694248; called by muse, varscan2
- GPR149 | c.93C>A p.T31= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV101078271, COSV101078820; called by muse, mutect2, varscan2
